Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5J6, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5J6-01A (Primary Tumor).

[page 1 of 2]
Patient Name:

Sex: Female

ICD-O-3

Carcinoma, Adrenal Cortical
8870/3

Site: (R) Adrenal Gland
Cortex C74.0

QID 1/30/13

Macroscopy

Two vessel containing a material immersed in formaldehyde solution, described as following: 1. Right adrenal mass, weighting 1370 g and measuring 20 x 13 x 7 cm, with a grayish and homogeneous external surface. The cut surface is heterogeneous, characterized by white areas and purple areas with a firm consistency. Fragment of a rib bone, measuring 15 x 3 cm with an habitual aspect. 2. Hepatic biopsy – an irregular dark brown fragment measuring 2 x 1 cm.

Conclusion:

1. Product of right nephrectomy and right adrenal mass resection: Adrenocortical carcinoma with the following features:

- Largest diameter – 20 cm.
- Nuclear grade (Fuhrman) – 3
- Diffuse architectural pattern – present
- Clear cells in < 25% of the neoplasm – present
- Areas on necrosis – not detected
- Mitotic count – <5 in 50 H.P.F.
- Atypical mitosis – not detected
- Capsular invasion – not detected
- Venous invasion – not detected
- Sinusoidal invasion – not detected
- WEISS SCORE = 3

[page 2 of 2]
- Renal parenchyma without evidence of neoplastic infiltration

2. Liver biopsy – Hyperplastic regenerative nodule.

Immunohistochemical markers:

- Melan A – focally positive
- Inhibin – positive
- 35BH11 – focally positive
- cytokeratin 20 – negative
- cytokeratin 7 – negative
- Sinaptophysin – negative
- Hep-Par 1 – negative
- Chromogranin – negative
- CEA – negative
- Calretinin – negative

Diagnostic Discrepancy		///

Source: NCI Genomic Data Commons file 9b7da97f-d947-47bd-9228-dad4ca03b25d (TCGA-OR-A5J6.F664D25E-9050-460D-AEAE-AA4BFA515453.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).